Surgical pathology report (de-identified scan), TCGA case TCGA-26-1438, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-1438-01A (Primary Tumor).

[page 1 of 2]
Case Type: [REDACTED]

Accession #: [REDACTED]

Name: [REDACTED]

MRN: [REDACTED]

Pt. Location: [REDACTED]

Date Received: [REDACTED]

Date of Collection: [REDACTED]

Ref. MD: [REDACTED]

26-1438

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Brain tumor (88307) A. Frozen Section Charge (88331)
A. Frozen Section Charge, Additional Block(s) (88332) B. Brain
tumor (88307) B. Glial Fibrill. Acid Prt (88342) B.
KPl-Macrophage, CD68 (88342) B. Pan-Cytokeratin (88342) B.
KI-67, Nuclear Antigen, Mib1 (88342) B. CD31 (88342) B.
Reticulin-Gordon&Sweet (88313) B. Neurofilament / NF (88342)
B. GMS Fungus (88312) B. Gram Stain (88312) B. Tosoplasma
Gondii, TOXO (88342)

CLINICAL HISTORY: [REDACTED] with complaints of headache, in
today for right crani for tumor.

GROSS DESCRIPTION:

Received the following specimens in the Department of Pathology, labeled
with the patient's name and hospital #:

A. "Brain tumor"

B. "Brain tumor"

A. The specimen is received without fixative and consists of a 0.9 x
0.8 x 0.7 cm portion tan to red-brown soft tissue. A representative
portion is submitted for frozen section in two parts; the frozen section
diagnosis is "Proliferated glia with necrosis and reactive changes, most
consistent with malignant glioma" per [REDACTED] The frozen section
tissue is resubmitted in FSA1 and FSA2, and the remaining tissue is
submitted in A3, for permanent processing. [REDACTED]

B. The specimen is received without fixative and consists of a 2.2 x
2.0 x 1.9 x 0.8 cm aggregate of beige to gray-tan granular tissue and a
small amount of blood clot. A portion is submitted for [REDACTED]
for research. The remaining tissue is submitted in B1-B3, for permanent
processing. [REDACTED]

DIAGNOSIS:

A. "Brain tumor" , biopsy: Glioblastoma multiforme (WHO
Grade IV astrocytoma) (see comment).

B. "Brain tumor", excision: Glioblastoma multiforme (WHO
Grade IV astrocytoma) (see comment).

[page 2 of 2]
[REDACTED]

Comment: This infiltrative (NF-immunoperoxidase), highly anaplastic, and extensively necrotic tumor is comprised of a pleomorphic population of often somewhat epithelioid-appearing cells that are, nevertheless, virtually all GFAP-immunoreactive (and PanCk-immunonegative). The tumor is mitotically active (with foci with almost 40% of nuclei Kii67-immunolabelled) and exhibits focally pronounced vascular/endothelial hyperplasia (CD31-immunoperoxidase and Retic stain). The tumor necrosis is associated, in some areas, with peripheral "pseudopalisading" of nuclei, but in other areas is associated with an unusually pronounced macrophagic (Kp1-immunoperoxidase) and even neutrophilic cellular reaction (Gram and GMS stains and Toxo-immunoperoxidase are negative). "I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

ICD9 Codes: 191.9

Diagnostic/Retrieval Codes: TX2000 M94403 TX2000 M94403

Note: Test systems have been developed and their performance characteristics determined by [REDACTED] Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Pathologist

Electronically signed [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 31d4c61f-ee08-4a53-a5a8-a453d8b3a71f (TCGA-26-1438.491BF470-5482-4560-8140-543DE057C069.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).